Somatic mutation profile of tumor specimen TCGA-BP-4983-01A (aliquot TCGA-BP-4983-01A-01D-1462-08) from TCGA case TCGA-BP-4983, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 67.2 years (24,558 days).
Specimen TCGA-BP-4983-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3da47737-15e3-43ab-ae75-7424b058c125.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4983-11A (Solid Tissue Normal), aliquot TCGA-BP-4983-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d72fd763-7db0-4c57-8140-03fb929f03b1

The open-access MAF lists 76 somatic variants for this specimen: 56 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 44, Silent 20, Nonsense Mutation 7, Frame Shift Ins 2, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TUBGCP6 | c.2356C>T p.R786* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as rs772174079, COSV50556783, COSV99956455; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.5498G>A p.R1833Q | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374948280; called by muse, mutect2, varscan2
- ABCC5 | c.2834C>T p.S945F | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.618); catalogued as rs1158691953, COSV55596793; called by muse, mutect2, varscan2
- ACAN | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs370626315; called by muse, mutect2, varscan2
- AMPH | c.336A>T p.K112N | Missense Mutation (SNP) | VAF 118/432 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57739713, COSV57758358; called by muse, mutect2, varscan2
- ASXL1 | c.2989G>T p.E997* | Nonsense Mutation (SNP) | VAF 24/96 reads (25%) | catalogued as COSV60123031; called by muse, mutect2, varscan2
- ATG2B | c.2552A>G p.K851R | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.985); catalogued as COSV63425864; called by muse, mutect2, varscan2
- CACNA1E | c.928G>T p.G310W | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62427628; called by muse, mutect2, varscan2
- CDH13 | c.905A>T p.D302V | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51871263; called by muse, mutect2
- CHAD | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51973734; called by muse, mutect2, varscan2
- CYLC1 | c.328C>T p.L110F | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.364); catalogued as COSV61416232; called by muse, mutect2, varscan2
- CYP2B6 | c.908C>T p.T303I | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.595); catalogued as COSV57845624; called by muse, mutect2, varscan2
- ELP2 | c.2210G>T p.R737L | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); catalogued as COSV60854683; called by muse, mutect2, varscan2
- EP400 | c.3205C>T p.L1069F | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV57787197; called by muse, varscan2
- EPB41L4B | c.1880G>A p.G627D | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs1479548588, COSV65805194; called by muse, mutect2
- FARP2 | c.1375C>A p.Q459K | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV50882692; called by muse, varscan2
- GOLT1A | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs150924607; called by muse, mutect2, varscan2
- HDAC9 | c.172C>A p.Q58K | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV67786033; called by muse, mutect2, varscan2
- HS3ST3A1 | c.794C>T p.T265I | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs1415862721, COSV99403971; called by muse, mutect2, varscan2
- KIF12 | c.595C>G p.R199G (on ENST00000640217; = p.R61G on NM_138424.1) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as COSV65118459; called by muse, varscan2
- LRRIQ1 | c.1723A>C p.I575L | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV67834605, COSV67839226; called by muse, mutect2, varscan2
- MCF2L2 | c.694A>G p.S232G | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1560019087, COSV61061937; called by muse, mutect2, varscan2
- MLF2 | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.503); catalogued as COSV52572203; called by muse, mutect2
- MMUT | c.1192A>G p.T398A | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV51285086; called by muse, mutect2, varscan2
- MOSPD3 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.945); catalogued as COSV56158987; called by muse, mutect2
- MRC2 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.24); catalogued as rs572758323, COSV57644925; called by muse, mutect2, varscan2
- MROH9 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773196117, COSV100883130, COSV63013377; called by muse, mutect2, varscan2
- MUC17 | c.7079C>A p.T2360K | Missense Mutation (SNP) | VAF 76/436 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.247); catalogued as rs143338962, COSV60304365; called by muse, mutect2, varscan2
- OR2T4 | c.374C>A p.S125* | Nonsense Mutation (SNP) | VAF 27/296 reads (9%) | catalogued as COSV63545201; called by muse, mutect2
- OR52N4 | c.211A>G p.T71A | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.117); catalogued as COSV57891349; called by muse, mutect2
- PAXBP1 | c.2054T>G p.L685R | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51612552; called by muse, mutect2, varscan2
- PCARE | c.1618A>C p.M540L | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.421); catalogued as COSV59058402; called by muse, mutect2
- PCBP1 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 26/267 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV57852010; called by muse, mutect2, varscan2
- PDCD6IP | c.2167C>T p.P723S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs1467226462, COSV56245934; called by muse, mutect2, varscan2
- PLCB2 | c.403A>T p.K135* | Nonsense Mutation (SNP) | VAF 13/60 reads (22%) | catalogued as COSV53038281, COSV99541678; called by muse, mutect2, varscan2
- PRDM13 | c.2039A>G p.K680R | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.994); catalogued as COSV65030759; called by muse, varscan2
- PTBP2 | c.343G>C p.A115P (on ENST00000426398 / NM_001300986.2; = p.A107P on NM_021190.4) | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64626650; called by muse, mutect2
- RABGAP1 | c.1323G>A p.W441* | Nonsense Mutation (SNP) | VAF 24/245 reads (10%) | catalogued as COSV65396086; called by muse, mutect2
- RALGAPA1 | c.4672C>T p.Q1558* | Nonsense Mutation (SNP) | VAF 19/125 reads (15%) | catalogued as COSV51897719; called by muse, mutect2, varscan2
- SHKBP1 | c.1256G>T p.G419V | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV52544015; called by muse, mutect2
- SLC25A28 | c.550C>A p.H184N | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65125611, COSV65125740; called by muse, mutect2
- SPEN | c.3385G>A p.V1129I | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs759801779, COSV65361082; called by muse, mutect2, varscan2
- TAFA1 | c.257A>G p.D86G | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV72041245; called by muse, mutect2, varscan2
- TMA16 | c.236A>C p.E79A | Missense Mutation (SNP) | VAF 6/158 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as COSV62188077; called by muse, mutect2
- TRAF7 | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58218586; called by muse, mutect2
- UGT2A3 | c.1448G>T p.W483L | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV52362254; called by muse, mutect2
- UGT2B7 | c.222T>G p.I74M | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV59442291; called by muse, mutect2, varscan2
- VARS2 | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 16/260 reads (6%) | catalogued as COSV58915169; called by muse, mutect2
- VPS13C | c.8055+1G>T p.X2685_splice (on ENST00000644861 / NM_020821.3; = p.X2642_splice on NM_017684.5) | Splice Site (SNP) | VAF 4/56 reads (7%) | catalogued as COSV51426226; called by muse, mutect2
- XRRA1 | c.1999T>C p.Y667H | Missense Mutation (SNP) | VAF 87/324 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs771101702, COSV55135940; called by muse, mutect2, varscan2
- ZNF32 | c.298A>G p.T100A | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV100986527, COSV65642001; called by muse, mutect2
- BANK1 | c.337del p.T113Lfs*6 | Frame Shift Del (DEL) | VAF 24/156 reads (15%) | called by mutect2, pindel*, varscan2
- HEATR9 | c.644T>C p.V215A | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LRBA | c.5489del p.H1830Lfs*7 | Frame Shift Del (DEL) | VAF 14/113 reads (12%) | called by mutect2, pindel, varscan2
- SETD2 | c.6861_6862insAT p.P2288Ifs*22 | Frame Shift Ins (INS) | VAF 19/99 reads (19%) | called by mutect2, pindel, varscan2
- ZNF84 | c.1707dup p.P570Tfs*3 | Frame Shift Ins (INS) | VAF 25/193 reads (13%) | called by mutect2, varscan2
- ASPM | c.3901T>C p.L1301= | Silent (SNP) | VAF 51/285 reads (18%) | catalogued as COSV54138164, COSV54139333; called by muse, mutect2, varscan2
- CADM3 | c.1125C>T p.D375= (on ENST00000368125 / NM_001127173.3; = p.D409= on NM_021189.5) | Silent (SNP) | VAF 18/142 reads (13%) | catalogued as rs143855176; called by muse, mutect2, varscan2
- CD79B | c.15G>A p.A5= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs199930415, COSV50076472; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDH20 | c.1023G>A p.L341= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as rs867323976, COSV53018669; called by muse, mutect2
- EPHB2 | c.1044C>T p.R348= | Silent (SNP) | VAF 26/197 reads (13%) | catalogued as rs561374198, COSV65867079; called by muse, mutect2, varscan2
- GNAI2 | c.309C>T p.D103= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as rs781903414, COSV56492928; called by muse, mutect2, varscan2
- GPR174 | c.228C>A p.I76= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV52134540; called by muse, mutect2, varscan2
- HCN3 | c.465T>C p.A155= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV64235317; called by muse, mutect2, varscan2
- HERC2 | c.2604G>A p.T868= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs139718674, COSV55334321; called by muse, mutect2, varscan2
- LPIN3 | c.2355C>T p.F785= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as COSV60038886; called by muse, mutect2, varscan2
- LRP1 | c.11799G>A p.A3933= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs746862323, COSV54519223; called by muse, mutect2, varscan2
- NEGR1 | c.564G>A p.L188= | Silent (SNP) | VAF 7/105 reads (7%) | catalogued as COSV60874770; called by muse, mutect2
- NIN | c.363T>G p.P121= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV55407375; called by muse, mutect2, varscan2
- OSBP2 | c.438G>A p.A146= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV60250151; called by muse, mutect2
- RBM33 | c.2622T>G p.L874= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV56637482; called by muse, mutect2, varscan2
- RTKN2 | c.1398A>G p.L466= | Silent (SNP) | VAF 31/214 reads (14%) | catalogued as COSV59524625; called by muse, mutect2, varscan2
- RYR3 | c.6112T>C p.L2038= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs774180939, COSV66809442; called by muse, mutect2, varscan2
- SDK1 | c.1806G>T p.R602= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV67389675; called by muse, mutect2
- SLC38A10 | c.2220C>T p.D740= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as rs1450065324, COSV55849620; called by muse, mutect2, varscan2
- SND1 | c.513T>C p.H171= | Silent (SNP) | VAF 25/217 reads (12%) | catalogued as COSV61249771; called by muse, mutect2, varscan2
